CPTAC case SC-0153 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3892ec45-cf98-4c9a-972e-d5b3b979c54b

Demographics
Sex at birth: male; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 90 years or older (exact value withheld by GDC); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: M0; Progression or recurrence: no; Days to last follow up: 122 days; Clark level: V.
   Pathology details: Breslow thickness: 7.

Biospecimens (1 sample)
- Sample S-1701-001806: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 349 mg; Method of sample procurement: Tumor Resection.
